Surgical pathology report (de-identified scan), TCGA case TCGA-44-2664, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-2664-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Right lower wedge
- B. Right lower lobe
- C. Node level 12
- D. Node level 7
- E. Node level 9
- F. Node level 11

CLINICAL NOTES

PRE-OP DIAGNOSIS: Pulmonary nodule.

FROZEN SECTION DIAGNOSIS

AFS: Right lung wedge resection - Adenocarcinoma.

GROSS DESCRIPTION

A. Received is a container labeled with the patient's name, medical record number and "right lower wedge". The specimen consists of a single piece of pulmonary parenchyma with a staple line along one edge and measuring 10 x 4.5 x 4 cm. in greatest dimensions. The staple line measures 8 cm. in length. The staple line is trimmed and the specimen is sectioned. On cut section, there is a relatively well-circumscribed, rubbery tan tumor mass, which measures 2.5 x 1.9 x 1.8 cm. in greatest dimensions. This mass comes to within 0.5 cm. of the stapled surgical margin. RS-AFS, A1-A5 - Tumor mass, entirely submitted; A6 - representative section of pulmonary parenchyma from adjacent to stapled surgical margins.

B. Received fresh labeled "right lower lobe" is a 137 gm., 14.0 x 9.0 x 5.5 cm. lobectomy specimen with attached 1.0 cm. in length, 1.8 x 1.5 cm. in diameter bronchial stump. Several soft gray black tissues in keeping with lymph nodes measuring up to 1 cm. in greatest dimension are recovered from the hilar region. An irregular 21.5 cm. staple line is present along the medial aspect of the specimen. A staple line is removed and the underlying surface

GROSS DESCRIPTION

is inked blue. On sectioning no discrete mass lesion or abnormality

is identified subjacent to the aforementioned staple line or throughout the remainder of the specimen. The parenchyma is spongiform tan red. Representative sections are submitted in 8 blocks as labeled. RS-8

BLOCK SUMMARY: 1 - bronchial stump margin; 2 - vascular margins; 3 through 6 - random subjacent to staple line; 7 - random normal; 8 - five whole presumptive lymph nodes from hilar region.

[page 2 of 3]
-
- C. Received fresh labeled "node level 12" are two soft gray black tissues measuring 0.4 and 0.7 cm. in greatest dimension which are submitted in toto. AS-1
- D. Received fresh labeled "node level 7" is a fragmented 1.6 x 1.3 x 0.2 cm. soft gray black-red tissue which is quadrisected and entirely submitted in one block. AS-1
- E. Received fresh labeled "node level 9" is a slightly fragmented 0.6 x 0.5 x 0.15 cm. portion of tan red-gray tissue which is submitted in toto. AS-1
- F. Received fresh labeled "node level 11" are three soft fragmented gray black tissues averaging 0.25 cm. in greatest dimension which are submitted in toto. AS-1
-

MICROSCOPIC DESCRIPTION

- A. The following template applies to the right lower wedge resection of the lung.
- Histologic type: Adenocarcinoma.
- Histologic grade: Poorly differentiated.
- Primary tumor (pT): Primary tumor measures 2.5 cm in greatest dimensions.
- The visceral pleura was disrupted prior to receipt in laboratory.

MICROSCOPIC DESCRIPTION

However, microscopically there is a suggestion of visceral pleural invasion.

Margins of resection: Uninvolved.

Direct extension of tumor: Not identified.

Venous (large vessel) invasion: Not identified.

Arterial (large vessel) invasion: Not identified.

Lymphatic (small vessel) invasion: Not identified.

Regional lymph nodes (pN): See additional specimens (pN0).

Distant metastasis (pM): Cannot be evaluated by this specimen (pMX).

Other findings: None.

B. Sections of the right lower lobe completion lobectomy demonstrate interalveolar histiocytes and hemorrhage related to surgical procedure but no evidence of residual malignancy. Two lymph nodes on the specimen are negative for metastatic disease.

- no C. The level 12 lymph nodes demonstrate four nodes with evidence of metastasis.
- D. The level 7 lymph nodes demonstrate seven lymph nodes with no evidence of metastasis.

[page 3 of 3]
-
- E. The level 9 lymph node tissue demonstrates only fibrovascular tissue. No nodes are identified.
F. THE level 11 lymph nodes demonstrate three nodes with no evidence of metastatic disease.

14, 3x3, 4x3

DIAGNOSIS

- A. Lung, right lower lobe, wedge resection:
Adenocarcinoma, poorly differentiated, 2.5 cm in greatest dimension.

DIAGNOSIS

- Surgical margins uninvolved.
B. Lung, right lower lobe, lobectomy:
No carcinoma identified.
Two lymph nodes with no evidence of metastatic disease (0/2).
C. Level 12 lymph nodes, resection:
No evidence of metastasis to four lymph nodes (0/4).
D. Level 7 lymph nodes, resection:
No evidence of metastasis to seven lymph nodes (0/7).
E. Level 9 lymph nodes, resection:
No nodes identified.
Fibrovascular tissue.
F. Level 11 lymph nodes, resection:
No evidence of metastasis to three lymph nodes (0/3).
-

Source: NCI Genomic Data Commons file 45170dab-8193-4844-9308-c823a60f239e (TCGA-44-2664.8AC6AEC3-D709-411F-9233-F264BAC80972.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).